Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4143, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4143-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Diagnosis:

Left kidney, radical nephrectomy.

- Renal cell carcinoma, clear cell type, tumor size 10 cm in greatest dimension, nuclear grade 3 (of 4), extending through capsule of kidney into perirenal adipose tissue, involving lumen of renal vein with tumor present at margin of renal vein.
- Adrenal gland with no tumor seen.
- Two perirenal lymph nodes with no tumor seen (0/2).

Comment:

None.

Clinical History:

with a left renal mass now undergoes left nephrectomy.

Gross Description:

Received is one appropriately labeled container.

Specimen fixation: formalin

Type of specimen: radical nephrectomy

Size and weight of specimen: 17 x 9 x 8.5 cm, 610 gm

Presence/absence of adrenal gland: present with no gross abnormality noted

Tumor description: Predominantly solid yellow and tan/white mass with a gelatinous appearance and irregular borders.

Tumor size: approximately 10 x 6 x 5.8 cm

Presence/absence of multicentricity: absent

Confinement/Non-confinement to kidney: appears to be confined within the renal capsule and there is perirenal

[page 2 of 3]
fat around the tumor

Extent of invasion:

Perirenal adipose tissue: tumor grossly does not involve the perirenal adipose tissue

Renal vein: tumor is present in lumen of renal vein and is present at margin

Ureter: not involved

Other organs: the adrenal gland does not appear to be involved

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: positive

Renal artery: negative

Ureter: positive

Description of kidney away from tumor: unremarkable

Lymph nodes (hilar): there is one large hilar possible lymph node which is bisected

Tissue submitted for special investigations: A portion of the tumor and the non-tumorous kidney are given to tissue procurement.

Block Summary:

A1-A2 - sections of the hilum

A3 - possible hilar lymph node bisected

A4 - adrenal gland

A5-A14 - representative sections of the tumor

A15 - non-tumorous renal parenchyma

Light Microscopy:

Light microscopic examination is performed

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): 3 (of 4)

Tumor size (greatest dimension): 10 cm

Extent of tumor invasion:

[page 3 of 3]
Capsular invasion/perirenal adipose tissue: capsular penetration identified with involvement of perirenal adipose tissue

Renal vein: involved with tumor

Ureter: not involved

Lymphovascular: not involved

Adjacent organs: not involved

Histologic assessment of surgical margins:

Perirenal adipose tissue: margins negative

Renal vein: involved at margin

Renal artery: not involved

Ureter: not involved

Adrenal gland: not tumor seen

Lymph nodes: no tumor seen in 2 perirenal lymph nodes

Source: NCI Genomic Data Commons file 6f88441b-044b-4450-82d7-e6bb68e4ed79 (TCGA-B8-4143.208D6D5E-C6BF-481B-9564-44BECA8B1FE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).